Somatic mutation profile of tumor specimen ASCProject_0024_T2_WES (aliquot ASCProject_0024_T2_WES_1) from CMI case ASCProject_0024, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 27.4 years (10,017 days).
Specimen ASCProject_0024_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0101545-21ff-40b6-b75f-1d4d24682a9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0024_SALIVA (Saliva), aliquot ASCProject_0024_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88492be5-8e50-4835-96d7-8c863415bd97

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COCH | chr14:30894909 A>T | 3'Flank (SNP) | VAF 12/160 reads (8%) | catalogued as rs1317914695, COSV53549614; called by muse, mutect2
